Gene-level copy-number profile of tumor specimen TCGA-VS-A9U6-01A from TCGA case TCGA-VS-A9U6, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVB; Tumor grade: GX; Age at diagnosis: 52.3 years (19,109 days).
Specimen TCGA-VS-A9U6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.c3ff93f6-e8c7-40c8-88f6-d0e3cfe6552f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VS-A9U6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/15395e76-4871-40dd-ae34-25799e4129fc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 48; copy number 1: 7,908; copy number 2: 40,135; copy number 3: 9,044; copy number 4: 560; copy number 5: 113; copy number 6: 1,062; copy number 7: 946.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VS-A9U6-01A-11D-A42N-01): tumor purity 0.65, ploidy 2.21, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 48 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:37,182,107–37,244,177, 4 genes: AC126118.1, AC097359.1, AC097359.3, AC097359.2.
- chr11:85,957,175–87,817,567, 44 genes (within-gene range 0–1): PICALM, RNU6-560P, LINC02695, FNTAP1, Metazoa_SRP, EED, MIR6755, AP003084.1, SETP17, HIKESHI, RN7SL225P, CCDC81, AP001831.1, PTP4A1P6, AP001148.1, ME3, AP003059.1, AP003059.2, PRSS23, MOB4P2, OR7E13P, AP000654.1, OR7E2P, AP001528.1, AP001528.2, FZD4, FZD4-DT, HNRNPCP8, TMEM135, XIAPP2, AP002967.1, AP001102.1, AP000811.1, PSMA2P1, AP003497.1, AP003497.2, AP001784.1, RNU6-1135P, U6, LINC02711, AP000756.1, MTCYBP41, AP000676.2, AP000676.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,121 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:40,344,850–40,876,670, 26 genes, copy number 6: SMAP2, AL031985.1, AL031985.4, ZFP69B, AL031985.3, AL603839.4, ZFP69, AL603839.3, EXO5, AL603839.1, AL603839.2, ZNF684, AL356379.2, AL356379.1, GTF2F2P2, RIMS3, AL031289.2, AL031289.1, NFYC-AS1, NFYC, MIR30E, MIR30C1, KCNQ4, RN7SL326P, CITED4, AC119677.1.
- chr1:43,145,153–46,176,488, 120 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr3:11,137,093–12,788,671, 34 genes, copy number 5: HRH1, AC083855.2, CHCHD4P4, ATG7, AC083855.1, AC026185.1, AC022001.1, VGLL4, AC022001.2, AC022001.3, TAMM41, FANCD2P2, CYCSP12, NUP210P2, MARK2P14, AC090958.1, RN7SL147P, SYN2, ACTG1P12, TIMP4, MTCO1P5, GSTM5P1, PPARG, AC091492.1, TSEN2, RNA5SP123, RNU6-377P, MKRN2OS, MKRN2, Metazoa_SRP, RAF1, CRIP1P1, TMEM40, KRT18P17.
- chr3:13,460,294–14,672,659, 28 genes, copy number 5–6: AC027124.2, AC027124.1, HDAC11-AS1, HDAC11, FBLN2, LINC00620, WNT7A, VN1R20P, FGD5P1, TPRXL, AC090004.2, VN1R21P, CHCHD4, TMEM43, AC090004.1, XPC-AS1, XPC, LSM3, AC093496.1, LINC01267, RNA5SP124, SLC6A6, GRIP2, RNU6-905P, RHBDF1P1, AC090952.2, AC090952.1, CCDC174.
- chr3:27,110,085–35,256,946, 102 genes, copy number 5–7 (broad region; genes not listed).
- chr3:35,650,197–35,651,961, 1 gene, copy number 5: ARPP21-AS1.
- chr3:90,261,414–198,222,513, 1,803 genes, copy number 6–7 (broad region; genes not listed).
- chr8:38,996,754–39,580,134, 7 genes, copy number 6 (within-gene range 2–6): ADAM9, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1.

Autosomal genes at a single copy (total copy number 1): 6,418. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
